Somatic mutation profile of tumor specimen ALCH-B1XL-TTP1-A (aliquot ALCH-B1XL-TTP1-A-3-0-D-A772-36) from ALCHEMIST case ALCH-B1XL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.3 years (27,883 days).
Specimen ALCH-B1XL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9952cb3a-28a9-4e7b-aa7d-cbc5cf03cbfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1XL-NB1-A (Blood Derived Normal), aliquot ALCH-B1XL-NB1-A-1-0-D-A772-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dba9ac0-49da-41b5-8e90-98e8d1c68d3d

The open-access MAF lists 573 somatic variants for this specimen: 376 protein-altering or splice-affecting, 118 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 310, Silent 118, Intron 41, Nonsense Mutation 36, Frame Shift Del 16, RNA 12, 5'UTR 9, 3'UTR 9, Splice Site 6, 3'Flank 6, Splice Region 4, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBX5 | c.426del p.A143Pfs*7 | Frame Shift Del (DEL) | VAF 33/164 reads (20%) | catalogued as rs1565941003, COSV59859763; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 19/45 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABI1 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); catalogued as COSV100697733; called by muse, mutect2, varscan2
- ADAM2 | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as COSV55863118; called by muse, mutect2, varscan2
- ADAMTS12 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs551278824, COSV61256246; called by muse, mutect2, varscan2
- ADGRG6 | c.3103C>A p.L1035M | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.581); catalogued as COSV51594266; called by muse, mutect2, varscan2
- ADGRL4 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV100876515; called by muse, varscan2
- AHNAK2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs774009909; called by muse, mutect2, varscan2
- ALB | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs75522063, CM900415; ClinVar: other; called by muse, mutect2, varscan2
- AMER3 | c.1010G>T p.R337M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV58466390; called by muse, mutect2, varscan2
- ARHGAP39 | c.3074C>A p.A1025D (on ENST00000276826 / NM_001308208.2; = p.A1056D on NM_025251.2) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV52773630, COSV99431074; called by muse, mutect2, varscan2
- ASMT | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs373339042, COSV67109849; called by muse, mutect2, varscan2
- AVIL | c.2208G>A p.M736I | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1268375438; called by muse, mutect2, varscan2
- BIRC7 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs912977719; called by muse, mutect2, varscan2
- BRD2 | c.1397C>G p.S466C | Missense Mutation (SNP) | VAF 29/351 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.865); catalogued as COSV66374550; called by muse, mutect2
- BRSK2 | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57540299; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CAGE1 | c.1481T>G p.L494R (on ENST00000512086; = p.L358R on NM_205864.3) | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV57076675; called by muse, mutect2, varscan2
- CCDC171 | c.1640A>T p.Q547L | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs1259605481; called by muse, mutect2, varscan2
- CCT7 | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs776682560; called by mutect2, varscan2
- CD163L1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs568854207, COSV58011767; called by muse, mutect2, varscan2
- CD19 | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV61187659; called by muse, mutect2, varscan2
- CDH10 | c.1932del p.L645Cfs*11 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | catalogued as COSV52576483; called by mutect2, pindel, varscan2
- CDKN1A | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 45/393 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750249677, COSV55191345; called by muse, mutect2, varscan2
- CFAP91 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV99847046; called by muse, mutect2, varscan2
- CHD1 | c.4877G>C p.R1626T | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV52341462; called by muse, mutect2, varscan2
- CLSTN3 | c.2032C>T p.H678Y | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as rs756578854; called by muse, mutect2
- COL1A2 | c.3675C>A p.H1225Q | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV51967377; called by muse, mutect2, varscan2
- CRACD | c.2345C>A p.P782H | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1429890963, COSV51716780; called by muse, mutect2, varscan2
- CRAMP1 | c.3325G>A p.G1109S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs551374666; called by muse, mutect2, varscan2
- CROCC | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as rs1263576257; called by muse, mutect2
- CSMD1 | c.2387del p.S796Lfs*4 (on ENST00000520002; = p.S795Lfs*4 on NM_033225.6) | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as COSV59299212, COSV59332226; called by mutect2, pindel, varscan2
- CUBN | c.8254G>T p.G2752C | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747786939, COSV64723780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP1A1 | c.1411del p.L471Wfs*16 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV65697171; called by mutect2, pindel, varscan2
- CYP27B1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV56985313; called by muse, mutect2
- CYP2B6 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.485); catalogued as rs1435601876; called by muse, mutect2, varscan2
- DEAF1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1219925185; called by muse, varscan2
- DMKN | c.58del p.E20Rfs*28 | Frame Shift Del (DEL) | VAF 74/131 reads (56%) | catalogued as COSV60084577; called by mutect2, pindel, varscan2
- DNAH5 | c.13730G>C p.R4577P | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV54205926, COSV99447576; called by muse, mutect2
- DPY19L2 | c.506del p.G169Dfs*4 | Frame Shift Del (DEL) | VAF 29/203 reads (14%) | catalogued as COSV60542442; called by mutect2, pindel, varscan2
- DSCAM | c.2458C>A p.R820S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV68024473; called by muse, mutect2, varscan2
- EIF3G | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99460664, COSV99461893; called by muse, mutect2
- ERCC4 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100319059; called by muse, mutect2, varscan2
- ERCC4 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as rs368830992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYS | c.2598C>A p.C866* | Nonsense Mutation (SNP) | VAF 26/222 reads (12%) | catalogued as COSV65518681; called by muse, mutect2
- FADS1 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs372910805; called by muse, mutect2, varscan2
- FAM47A | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100649744; called by muse, mutect2, varscan2
- FASTKD5 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 27/216 reads (13%) | catalogued as COSV99417472; called by muse, mutect2, varscan2
- FBN1 | c.3410G>T p.R1137L | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.574); catalogued as rs137854456, CM910154; called by muse, mutect2, varscan2
- FSTL4 | c.2148C>G p.I716M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV54775685; called by muse, mutect2, varscan2
- GABRA4 | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51935820; called by muse, mutect2, varscan2
- GABRR3 | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72115906; called by muse, mutect2
- GJA8 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs782253888, COSV53787656; called by muse, mutect2, varscan2
- GNAZ | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50738641; called by muse, mutect2, varscan2
- GPI | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62894718; called by muse, mutect2, varscan2
- GTDC1 | c.626G>C p.R209T | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.071); catalogued as COSV53998701; called by muse, mutect2
- HBM | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs1437861967, COSV100720796; called by muse, mutect2, varscan2
- HELB | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs749169621; called by muse, mutect2, varscan2
- HNRNPD | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1560441916; called by muse, mutect2, varscan2
- HS3ST3A1 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as rs767211034; called by muse, mutect2, varscan2
- ICE1 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV56831073; called by muse, mutect2, varscan2
- IPO8 | c.2997G>C p.E999D | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56246132; called by muse, mutect2, varscan2
- ITGA2 | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1207247098, COSV56859459; called by muse, mutect2, varscan2
- ITSN1 | c.4729G>A p.E1577K | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1028663752; called by muse, mutect2
- KALRN | c.4279G>T p.E1427* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV53761905; called by muse, mutect2
- KASH5 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 36/212 reads (17%) | catalogued as rs1322581823; called by muse, varscan2
- KCNMA1 | c.3296G>T p.R1099L (on ENST00000286628 / NM_001161352.2; = p.R1041L on NM_002247.4) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV54265081; called by muse, mutect2, varscan2
- KDM5A | c.2737G>T p.D913Y | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV66991434; called by muse, mutect2
- LETM2 | c.943C>T p.Q315* (on ENST00000379957 / NM_001286819.2; = p.Q220* on NM_144652.3) | Nonsense Mutation (SNP) | VAF 47/209 reads (22%) | catalogued as COSV52687555; called by muse, mutect2, varscan2
- LGI4 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 146/417 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.086); catalogued as rs1164091476; called by muse, varscan2
- LMO7 | c.688G>T p.D230Y (on ENST00000357063; = p.D245Y on NM_005358.5) | Missense Mutation (SNP) | VAF 48/463 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1033911574; called by muse, mutect2, varscan2
- LRFN5 | c.1760A>G p.Q587R | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs748893414, COSV53254964; called by muse, mutect2, varscan2
- MED13 | c.688A>G p.K230E | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV100784908; called by muse, mutect2, varscan2
- MGAT4C | c.1180del p.V394* | Frame Shift Del (DEL) | VAF 36/214 reads (17%) | catalogued as COSV100153071; called by mutect2, pindel, varscan2
- MICU2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs760247912; called by muse, mutect2, varscan2
- MOGS | c.1052G>C p.R351T | Missense Mutation (SNP) | VAF 100/377 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as rs368536824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRC1 | c.753C>A p.N251K | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs138394788; called by muse, varscan2
- MSR1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.701); catalogued as rs1232810247, COSV50521616; called by muse, mutect2, varscan2
- MUC16 | c.41622C>G p.D13874E | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs753851930; called by muse, mutect2, varscan2
- MUC5AC | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 27/361 reads (7%) | SIFT deleterious (0.02); catalogued as COSV100650628; called by muse, mutect2
- MXRA5 | c.3712C>G p.P1238A | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as COSV99476130; called by muse, mutect2, varscan2
- MYH3 | c.3136C>T p.R1046* | Nonsense Mutation (SNP) | VAF 51/324 reads (16%) | catalogued as rs748108904, COSV56866356; called by muse, mutect2, varscan2
- MYO15A | c.5719C>T p.L1907F | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs1413194161; called by muse, mutect2, varscan2
- MYO16 | c.5012C>A p.P1671H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100696699; called by muse, mutect2
- NBEAL1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 21/152 reads (14%) | catalogued as rs943542495, COSV101495839; called by muse, mutect2, varscan2
- NFIB | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.457); catalogued as rs992922055; called by muse, mutect2, varscan2
- NLK | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100817301; called by muse, varscan2
- NOD2 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs779346494; called by muse, mutect2, varscan2
- NPHS1 | c.3665G>A p.G1222E | Missense Mutation (SNP) | VAF 44/654 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs771640846, COSV62289805; called by muse, mutect2
- NPY | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV54215156; called by muse, mutect2, varscan2
- NSD3 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV100395881; called by muse, varscan2
- NUB1 | c.734G>C p.R245T | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV100879242; called by muse, varscan2
- OR2L13 | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.157); catalogued as COSV63560318; called by muse, mutect2
- OR4A5 | c.866C>A p.S289* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as rs760965103; called by muse, mutect2, varscan2
- OR5D16 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV65722731; called by muse, mutect2, varscan2
- PCDHA3 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100974220; called by muse, mutect2, varscan2
- PCDHB6 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50689499; called by muse, mutect2, varscan2
- PCDHB6 | c.1637G>T p.R546L | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50692656; called by mutect2, varscan2
- PCDHGC4 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 24/150 reads (16%) | catalogued as COSV52755065; called by muse, mutect2, varscan2
- PDGFRA | c.69C>A p.C23* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV57265611; called by muse, mutect2, varscan2
- PGGHG | c.1034A>C p.K345T | Missense Mutation (SNP) | VAF 95/152 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV67140696; called by muse, mutect2, varscan2
- PIAS1 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs750778840; called by muse, mutect2, varscan2
- PKP4 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1461427351; called by muse, mutect2
- PLCB4 | c.1684C>A p.H562N | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV53798020; called by muse, mutect2, varscan2
- POLB | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 74/347 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55183675; called by muse, mutect2, varscan2
- POTEE | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100389468, COSV58225660; called by muse, mutect2, varscan2
- PSKH2 | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1379631551; called by muse, mutect2, varscan2
- PTCHD4 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.944); catalogued as rs144280302; called by muse, mutect2
- PTPRC | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99049539; called by muse, mutect2, varscan2
- PXDNL | c.4387C>A p.R1463S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV62491202, COSV62493452; called by muse, mutect2, varscan2
- RABGAP1L | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 49/170 reads (29%) | catalogued as rs1264169815, COSV52293046; called by muse, mutect2, varscan2
- RYR1 | c.9998C>G p.S3333C | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs878944689; called by muse, mutect2, varscan2
- RYR1 | c.11326G>T p.E3776* | Nonsense Mutation (SNP) | VAF 32/368 reads (9%) | catalogued as COSV100617662; called by muse, mutect2
- SEMA4A | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.715); catalogued as COSV100740609; called by muse, mutect2, varscan2
- SETDB1 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV54979770, COSV54984186; called by muse, mutect2
- SI | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs552988486; called by muse, mutect2, varscan2
- SKA3 | c.1096A>T p.K366* | Nonsense Mutation (SNP) | VAF 62/184 reads (34%) | catalogued as COSV53434036; called by muse, mutect2, varscan2
- SORCS3 | c.2363T>G p.L788R | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV63799074; called by muse, mutect2
- TENM2 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.15); catalogued as COSV69128113; called by muse, varscan2
- TLR4 | c.394G>T p.V132L (on ENST00000355622 / NM_138554.5; = p.V92L on NM_003266.4) | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs769767782; called by muse, varscan2
- TLX2 | c.173C>G p.S58W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV99283788; called by muse, mutect2, varscan2
- TM9SF4 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs772417307; called by muse, mutect2, varscan2
- TMEM200B | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs772500468; called by muse, mutect2, varscan2
- TMEM72 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.854); catalogued as rs201160000; called by muse, mutect2, varscan2
- TRABD2A | c.868C>T p.Q290* (on ENST00000409520 / NM_001277053.2; = p.Q241* on NM_001080824.3) | Nonsense Mutation (SNP) | VAF 24/206 reads (12%) | catalogued as COSV59102952; called by muse, mutect2, varscan2
- TRMT12 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs769954903; called by muse, mutect2
- TTC12 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59098073; called by muse, mutect2, varscan2
- TTN | c.41630T>C p.V13877A (on ENST00000591111; = p.V6453A on NM_003319.4) | Missense Mutation (SNP) | VAF 46/256 reads (18%) | PolyPhen benign (0.013); catalogued as COSV60088910; called by muse, mutect2, varscan2
- UBR4 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64385874; called by muse, mutect2, varscan2
- UGT2B11 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs1169400462; called by muse, mutect2
- UROD | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 90/335 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV55798999; called by muse, mutect2, varscan2
- WDR25 | c.1508G>T p.R503L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.902); catalogued as COSV58934637, COSV58941232; called by muse, mutect2, varscan2
- WWP2 | c.1522-1G>C p.X508_splice | Splice Site (SNP) | VAF 27/181 reads (15%) | catalogued as COSV100598540; called by muse, varscan2
- XDH | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs200810102; called by muse, mutect2, varscan2
- YIPF7 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100274380, COSV60657355; called by muse, mutect2, varscan2
- ZAN | c.6561C>A p.F2187L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV61805817; called by muse, mutect2, varscan2
- ZBTB37 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as rs756381370; called by muse, mutect2, varscan2
- ZDHHC20 | c.252C>G p.F84L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100203357; called by muse, mutect2, varscan2
- ZMYND8 | c.3004C>T p.R1002W (on ENST00000311275 / NM_001363741.2; = p.R976W on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751016050, COSV53684506, COSV53695058; called by muse, mutect2, varscan2
- ZNF135 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100537054; called by muse, mutect2, varscan2
- ZNF23 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 27/170 reads (16%) | catalogued as rs777602194; called by muse, mutect2, varscan2
- ABCG2 | c.1285dup p.V429Gfs*30 | Frame Shift Ins (INS) | VAF 16/115 reads (14%) | called by mutect2, pindel, varscan2
- ACAP2 | c.1625C>G p.S542C | Missense Mutation (SNP) | VAF 51/630 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- ACOX1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY6 | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRG6 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFAP1 | c.1139G>T p.R380M | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AFG3L2 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHI1 | c.2590G>C p.D864H | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKR1D1 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); called by muse, varscan2
- ANK2 | c.7557T>A p.D2519E | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK3 | c.13122G>C p.K4374N (on ENST00000280772 / NM_001320874.2; = p.K998N on NM_001149.3) | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ANKRD12 | c.4066G>C p.E1356Q | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD36C | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.015); called by mutect2, varscan2
- ANO3 | c.2467G>C p.A823P | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ARHGAP33 | c.3266G>C p.R1089P | Missense Mutation (SNP) | VAF 83/114 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ARHGEF15 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ARIH2 | c.918G>C p.K306N | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARL9 | c.542C>G p.P181R (on ENST00000640821 / NM_001363794.2; = p.P39R on NM_206919.2) | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARSD | c.1702C>G p.L568V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASAP1 | c.2673_2674del p.R892Sfs*4 | Frame Shift Del (DEL) | VAF 33/239 reads (14%) | called by mutect2, pindel, varscan2
- ASIC3 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- ATRNL1 | c.3715A>G p.S1239G | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- BACH1 | c.1771A>T p.K591* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- BAHCC1 | c.3311C>G p.S1104* | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- BBOX1 | c.487del p.S163Qfs*37 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | called by mutect2, pindel, varscan2
- BNC2 | c.2504G>A p.C835Y | Missense Mutation (SNP) | VAF 58/467 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BST2 | c.411G>A p.L137= | Splice Region (SNP) | VAF 10/161 reads (6%) | called by muse, mutect2
- C19orf84 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- C2CD2L | c.894G>T p.L298F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- C2orf50 | c.392T>A p.L131Q | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- C4orf54 | c.3532G>T p.G1178C | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- C6orf136 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN8 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CAPRIN1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CARF | c.1444T>G p.S482A | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.375); called by muse, mutect2
- CCDC168 | c.7944_7951del p.N2650Tfs*2 | Frame Shift Del (DEL) | VAF 61/153 reads (40%) | called by mutect2, pindel, varscan2
- CCDC59 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CCHCR1 | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- CEP85L | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFAP65 | c.4257C>G p.I1419M | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CHD7 | c.1992G>C p.E664D | Missense Mutation (SNP) | VAF 46/392 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- CLVS2 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.373); called by muse, mutect2
- CNBD1 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.127); called by muse, mutect2
- COL22A1 | c.3976C>G p.P1326A | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2
- COL22A1 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL3A1 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- COL6A5 | c.237C>G p.H79Q | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CPAMD8 | c.1657C>T p.Q553* (on ENST00000651564; = p.Q506* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- CSMD1 | c.7435C>T p.L2479F (on ENST00000520002; = p.L2478F on NM_033225.6) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CSMD3 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.052); called by muse, mutect2
- CYP2C18 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- CYP46A1 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DBX2 | c.428G>C p.S143T | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCAF4L2 | c.845G>C p.G282A | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2
- DENND5A | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DGKQ | c.2269G>C p.D757H | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DIP2A | c.284-1G>A p.X95_splice | Splice Site (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- DIPK1C | c.696C>G p.H232Q | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- DLST | c.98-2A>T p.X33_splice | Splice Site (SNP) | VAF 30/266 reads (11%) | called by muse, mutect2, varscan2
- DNAH11 | c.3731T>G p.V1244G | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- DNHD1 | c.11053+3G>A | Splice Region (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- DOCK9 | c.3184G>A p.E1062K (on ENST00000376460 / NM_001366676.2; = p.E1063K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- DPP8 | c.2092G>T p.V698L (on ENST00000341861 / NM_001320875.2; = p.V682L on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DUSP12 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- DUSP28 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, varscan2
- EFR3B | c.1060A>G p.S354G | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- EGR4 | c.287C>A p.A96E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF2A | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- EIF2S3B | c.1339G>T p.V447F | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, varscan2
- EVC | c.983T>G p.L328R | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC2 | c.1199C>G p.P400R | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FAM114A2 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- FAM133B | c.62del p.G21Vfs*14 | Frame Shift Del (DEL) | VAF 53/293 reads (18%) | called by pindel, varscan2
- FAM151A | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM155B | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAM20C | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FANCM | c.3521C>T p.S1174F | Missense Mutation (SNP) | VAF 83/319 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- FBXL7 | c.317G>T p.R106I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FFAR4 | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- FGF23 | c.205A>T p.I69F | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2
- FKBP1C | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.213); called by muse, mutect2
- FUT9 | c.761C>G p.T254R | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- G2E3 | c.1650G>C p.Q550H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABARAPL1 | c.241A>T p.N81Y | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, varscan2
- GPR84 | c.584del p.G195Afs*51 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- GREB1L | c.2571C>A p.C857* | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- GRIK1 | c.2045C>A p.P682H | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HCN3 | c.2165G>T p.R722L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- HCN4 | c.2639C>A p.S880Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- HDAC9 | c.3044G>T p.R1015M (on ENST00000441542 / NM_178425.3; = p.R1012M on NM_178423.3) | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- HDLBP | c.2994G>A p.M998I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- HIVEP1 | c.2777G>A p.C926Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- HIVEP2 | c.4702G>A p.E1568K | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- HMGB4 | c.93dup p.P32Afs*8 | Frame Shift Ins (INS) | VAF 32/130 reads (25%) | called by mutect2, pindel*, varscan2
- HTR1F | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- HTRA3 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- IFNAR2 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.951); called by muse, mutect2
- IL17RD | c.1532T>A p.L511* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- INTS13 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQGAP3 | c.4674-2A>T p.X1558_splice | Splice Site (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- ITGA3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGAD | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, varscan2
- KCNC1 | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- KDM5C | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- KEAP1 | c.447G>C p.E149D | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- KIAA0586 | c.2407A>T p.S803C (on ENST00000619416 / NM_001244190.2; = p.S742C on NM_014749.5) | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- LCE1A | c.85T>C p.C29R | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.899); called by muse, mutect2
- LILRA2 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- LMNTD2 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- LRP1B | c.8652T>A p.C2884* | Nonsense Mutation (SNP) | VAF 29/132 reads (22%) | called by muse, mutect2, varscan2
- LRRC40 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC4B | c.1916C>A p.A639D | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC74B | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LXN | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- MADD | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- MAP4K1 | c.239G>C p.S80T | Missense Mutation (SNP) | VAF 179/423 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAT1A | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- MFSD9 | c.166-1G>T p.X56_splice | Splice Site (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- MOGS | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1625G>T p.S542I | Missense Mutation (SNP) | VAF 125/299 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- MRC1 | c.646A>T p.S216C | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, varscan2
- MRC2 | c.2521G>C p.E841Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- MROH1 | c.3247G>C p.E1083Q | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- MRPL50 | c.296A>T p.N99I | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTCL1 | c.3798C>A p.F1266L (on ENST00000306329 / NM_001378206.1; = p.F947L on NM_015210.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MUC16 | c.21476C>G p.S7159* | Nonsense Mutation (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- MUC16 | c.6643A>T p.T2215S | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); called by muse, mutect2
- MUC4 | c.9895G>T p.V3299F | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MUC7 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 59/330 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO18B | c.6366G>T p.E2122D | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NACA2 | c.506A>T p.E169V | Missense Mutation (SNP) | VAF 77/397 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- NAMPT | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.029); called by muse, mutect2
- NBEA | c.3163C>A p.L1055I | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NDUFAB1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NEDD9 | c.2443A>G p.T815A | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NES | c.4487_4492delinsA p.S1496Yfs*6 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | called by pindel, varscan2*
- NOP53 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NPC1L1 | c.3798C>A p.F1266L | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRCAM | c.2759C>A p.P920H (on ENST00000379028 / NM_001371124.1; = p.P904H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRXN3 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OGDHL | c.2812G>C p.E938Q | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2
- OPLAH | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2AT4 | c.334T>C p.F112L | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- OR4C5 | c.853T>A p.S285T | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.01); called by muse, mutect2
- OR4E2 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR52J3 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR6C2 | c.652T>A p.Y218N | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OR6N2 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- PAGE4 | c.209del p.K70Rfs*12 | Frame Shift Del (DEL) | VAF 30/101 reads (30%) | called by pindel, varscan2
- PBDC1 | c.628A>C p.K210Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PBX2 | c.1103_1109delinsG p.S368_S370delinsC | In Frame Del (DEL) | VAF 66/204 reads (32%) | called by pindel, varscan2*
- PCARE | c.3627C>A p.D1209E | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGA11 | c.1289G>T p.S430I | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PDE12 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, varscan2
- PDE3A | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PDHA2 | c.667A>C p.N223H | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PEG3 | c.170T>G p.F57C | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PIEZO2 | c.2015T>C p.M672T | Missense Mutation (SNP) | VAF 103/334 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PKDCC | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKNOX1 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2
- PLCB1 | c.542A>T p.D181V | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- PNLIP | c.1339A>G p.N447D | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PNMA3 | c.1358G>A p.W453* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.378C>G p.F126L | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- POLL | c.417G>T p.L139F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.388); called by muse, mutect2
- POLR3E | c.282-7G>T | Splice Region (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- PPP4R3C | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKG2 | c.551T>A p.M184K | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRPF40A | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.201); called by muse, mutect2
- PSMG1 | c.860A>T p.Y287F | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTDSS2 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 56/656 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2
- RALGPS2 | c.1075A>T p.S359C | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RASEF | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RB1CC1 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGPD4 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 8/225 reads (4%) | called by muse, mutect2
- RHAG | c.1124G>C p.G375A | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- RIF1 | c.2170A>G p.T724A | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RNF17 | c.4807G>A p.D1603N | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RP1L1 | c.7034C>T p.P2345L | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RP1L1 | c.2081G>C p.R694T | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- RPL31 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RPTN | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SCN10A | c.662G>C p.R221T | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDK1 | c.5127G>T p.Q1709H | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SH3TC2 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 71/469 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SIPA1L1 | c.4064G>C p.G1355A | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC24A4 | c.482_524del p.V161Afs*10 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- SLC25A51 | c.870T>G p.Y290* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- SLC9A9 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- SMC3 | c.2873A>T p.Q958L | Missense Mutation (SNP) | VAF 65/472 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SMPDL3A | c.1104G>T p.W368C | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SOCS4 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- SPANXN2 | c.464A>G p.D155G | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.039); called by muse, varscan2
- SPATA31D1 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- SPATA32 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- SPATA48 | c.50G>T p.R17M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- SPTB | c.2837G>T p.R946L | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SREK1 | c.383T>G p.V128G | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- STPG2 | c.483C>G p.S161R | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUPT3H | c.135-8T>A | Splice Region (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- SYNE1 | c.5832A>T p.Q1944H (on ENST00000367255 / NM_182961.4; = p.Q1951H on NM_033071.3) | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- TCTN3 | c.1420A>T p.T474S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TEX14 | c.3650G>T p.G1217V (on ENST00000240361 / NM_001201457.2; = p.G1171V on NM_031272.5) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TMEM256 | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- TMPRSS11B | c.176dup p.N59Kfs*2 | Frame Shift Ins (INS) | VAF 42/278 reads (15%) | called by mutect2, pindel, varscan2
- TNC | c.4840G>C p.E1614Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TNK1 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TPX2 | c.1642C>A p.Q548K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- TRAF3IP2 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- TRBV23-1 | c.317C>G p.T106R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TRIM25 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- TULP3 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- UBE2W | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- UTP15 | c.575T>G p.F192C | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VWA2 | c.298C>G p.H100D | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- WBP11 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- WDHD1 | c.902A>T p.E301V | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- WDHD1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 29/402 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.591); called by muse, mutect2
- WNK3 | c.4942G>C p.D1648H | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WNT9A | c.838A>T p.S280C | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ZACN | c.787G>C p.G263R | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZBTB40 | c.2461+1G>T p.X821_splice | Splice Site (SNP) | VAF 88/266 reads (33%) | called by muse, varscan2
- ZDHHC17 | c.374C>G p.S125* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- ZEB2 | c.1355C>A p.T452N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF142 | c.5281G>C p.E1761Q (on ENST00000411696 / NM_001379660.1; = p.E1561Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF222 | c.852_853del p.Y285Qfs*3 | Frame Shift Del (DEL) | VAF 133/367 reads (36%) | called by mutect2, pindel, varscan2
- ZNF267 | c.1336A>C p.N446H | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- ZNF532 | c.2659T>A p.S887T | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF605 | c.138A>T p.E46D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZNF626 | c.1243C>A p.H415N | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF658 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.319); called by mutect2, varscan2
- ZNF768 | c.1580A>T p.D527V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ZNF804A | c.3536C>T p.P1179L | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2
- ZNF835 | c.1111T>C p.F371L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS20 | c.84C>A p.P28= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- AGAP1 | c.2091G>A p.T697= (on ENST00000304032 / NM_001037131.3; = p.T644= on NM_014914.5) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs768870974, COSV58326909; called by mutect2, varscan2
- AKT2 | c.232C>T p.L78= | Silent (SNP) | VAF 126/191 reads (66%) | called by muse, mutect2, varscan2
- ANKRD30A | c.627C>T p.L209= (on ENST00000611781; = p.L153= on NM_052997.2) | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as rs1437879024, COSV64611399; called by muse, mutect2
- ARHGEF10L | c.1614C>T p.L538= | Silent (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- ATF6B | c.789C>T p.P263= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- CAPN1 | c.975C>T p.L325= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- CES3 | c.648C>T p.F216= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs768694829, COSV57592693; called by muse, mutect2, varscan2
- CSMD3 | c.8205C>A p.A2735= | Silent (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- CTSK | c.369G>A p.K123= | Silent (SNP) | VAF 30/324 reads (9%) | catalogued as COSV55011067; called by muse, mutect2
- CYP17A1 | c.1179C>T p.I393= | Silent (SNP) | VAF 82/259 reads (32%) | catalogued as rs763544377; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP1A1 | c.99C>A p.V33= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV101122387; called by muse, mutect2, varscan2
- CYP2C18 | c.363G>A p.K121= | Silent (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- DHRS1 | c.477C>T p.F159= | Silent (SNP) | VAF 73/273 reads (27%) | called by muse, mutect2, varscan2
- DSG1 | c.1296G>C p.L432= | Silent (SNP) | VAF 72/444 reads (16%) | catalogued as rs1185788450; called by muse, mutect2, varscan2
- DST | c.13764T>C p.D4588= (on ENST00000361203 / NM_001374722.1; = p.D2176= on NM_015548.5) | Silent (SNP) | VAF 28/246 reads (11%) | called by muse, varscan2
- EEF1A2 | c.267C>T p.I89= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- ENTPD8 | c.1281C>T p.L427= (on ENST00000371506 / NM_001033113.2; = p.L390= on NM_198585.3) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs144921257; called by muse, mutect2, varscan2
- EYS | c.6162A>T p.A2054= | Silent (SNP) | VAF 56/307 reads (18%) | catalogued as rs1164261609; called by muse, mutect2, varscan2
- FAM102A | c.78C>T p.F26= | Silent (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- FAM193A | c.3513C>G p.L1171= | Silent (SNP) | VAF 26/192 reads (14%) | called by muse, mutect2, varscan2
- FAM71D | c.417G>C p.L139= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as COSV100315144, COSV61296395; called by muse, mutect2, varscan2
- FANCB | c.2091G>T p.P697= | Silent (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- FCGR2A | c.831C>A p.T277= (on ENST00000271450 / NM_001136219.3; = p.T276= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/502 reads (4%) | called by muse, mutect2
- FGF10 | c.456G>A p.L152= | Silent (SNP) | VAF 46/432 reads (11%) | called by muse, mutect2, varscan2
- FGF23 | c.204C>A p.T68= | Silent (SNP) | VAF 18/231 reads (8%) | called by muse, mutect2
- FLNA | c.6492G>C p.L2164= (on ENST00000369850 / NM_001110556.2; = p.L2156= on NM_001456.3) | Silent (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- FLRT2 | c.1242A>G p.R414= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- FOXD4L4 | c.144G>A p.Q48= | Silent (SNP) | VAF 44/658 reads (7%) | called by muse, mutect2
- FOXF2 | c.1221A>G p.K407= | Silent (SNP) | VAF 94/311 reads (30%) | called by muse, mutect2, varscan2
- GLRB | c.285A>G p.Q95= | Silent (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- GPC5 | c.777G>A p.P259= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs532850832; called by muse, mutect2, varscan2
- GRIP1 | c.1890G>C p.R630= (on ENST00000359742 / NM_001379345.1; = p.R578= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 33/206 reads (16%) | called by muse, mutect2, varscan2
- HAS1 | c.909C>G p.S303= | Silent (SNP) | VAF 66/137 reads (48%) | catalogued as rs1279145187; called by muse, mutect2, varscan2
- HIVEP1 | c.600G>A p.L200= | Silent (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- HIVEP2 | c.5616A>G p.E1872= | Silent (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2
- HMX2 | c.51C>G p.V17= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- HTT | c.4077C>T p.F1359= | Silent (SNP) | VAF 34/211 reads (16%) | called by muse, mutect2, varscan2
- IL36B | c.465G>T p.R155= | Silent (SNP) | VAF 65/280 reads (23%) | called by muse, mutect2, varscan2
- ITIH2 | c.942C>T p.V314= | Silent (SNP) | VAF 24/208 reads (12%) | catalogued as rs1388892519, COSV100623390; called by muse, varscan2
- KCND3 | c.795G>T p.V265= | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- KIAA1549L | c.5457C>A p.T1819= (on ENST00000321505; = p.T2116= on NM_012194.3) | Silent (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- KIF2B | c.411C>T p.S137= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV52127037, COSV52134855; called by muse, mutect2, varscan2
- KRTAP10-1 | c.561C>A p.V187= | Silent (SNP) | VAF 35/253 reads (14%) | catalogued as rs1477466265; called by muse, mutect2, varscan2
- LAPTM4A | c.279C>T p.I93= | Silent (SNP) | VAF 45/225 reads (20%) | called by muse, mutect2, varscan2
- LRRC24 | c.1419C>T p.I473= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1311068002; called by muse, mutect2, varscan2
- LRRC4B | c.1917C>G p.A639= | Silent (SNP) | VAF 12/16 reads (75%) | called by muse, mutect2, varscan2
- MAGEB1 | c.828C>A p.A276= | Silent (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- MAGEE1 | c.1821C>T p.L607= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2931G>A p.R977= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs768824507; called by muse, mutect2, varscan2
- MAPK4 | c.1017G>A p.L339= | Silent (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- MED25 | c.1167C>T p.L389= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs992676211; called by muse, mutect2, varscan2
- MELK | c.1116A>T p.I372= | Silent (SNP) | VAF 60/172 reads (35%) | called by muse, mutect2, varscan2
- MGAM2 | c.4938A>T p.T1646= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- MPV17 | c.123G>T p.R41= | Silent (SNP) | VAF 117/274 reads (43%) | called by muse, mutect2, varscan2
- MUC5AC | c.15582C>G p.L5194= | Silent (SNP) | VAF 13/206 reads (6%) | catalogued as COSV100611308; called by muse, mutect2
- MUC6 | c.3189C>T p.V1063= | Silent (SNP) | VAF 67/94 reads (71%) | catalogued as rs954873903; called by muse, mutect2, varscan2
- MYBL1 | c.1527A>T p.T509= | Silent (SNP) | VAF 38/254 reads (15%) | called by muse, mutect2, varscan2
- MYOM2 | c.2340C>G p.L780= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV50709194; called by muse, mutect2, varscan2
- N4BP2L1 | c.153G>T p.P51= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- NAV3 | c.4068C>T p.G1356= | Silent (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- NCKAP1L | c.1641C>A p.I547= | Silent (SNP) | VAF 34/199 reads (17%) | catalogued as rs770470490, COSV53208981; called by muse, mutect2, varscan2
- NCKAP5 | c.3225A>T p.P1075= | Silent (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- NNMT | c.453C>T p.A151= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs771601164; called by muse, mutect2, varscan2
- NRDC | c.972G>T p.L324= | Silent (SNP) | VAF 67/302 reads (22%) | catalogued as rs1311087763; called by muse, mutect2, varscan2
- OR52H1 | c.351G>T p.L117= (on ENST00000322653; = p.L123= on NM_001005289.1) | Silent (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- OSGEP | c.69G>A p.K23= | Silent (SNP) | VAF 45/134 reads (34%) | called by muse, mutect2, varscan2
- OTX2 | c.693C>G p.L231= (on ENST00000408990 / NM_172337.3; = p.L239= on NM_021728.4) | Silent (SNP) | VAF 44/198 reads (22%) | catalogued as COSV100258125; called by muse, varscan2
- PABPC3 | c.1629C>G p.S543= | Silent (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2, varscan2
- PCDHA10 | c.114C>A p.A38= | Silent (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- PCDHA7 | c.132C>T p.F44= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV65341485; called by muse, varscan2
- PCDHB4 | c.1377C>T p.V459= | Silent (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- PCNT | c.2634C>T p.I878= | Silent (SNP) | VAF 19/165 reads (12%) | called by muse, mutect2, varscan2
- PIGK | c.1155T>G p.T385= | Silent (SNP) | VAF 22/246 reads (9%) | catalogued as COSV100892209; called by muse, mutect2
- PIK3CD | c.2577G>A p.L859= | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- PLEKHG4B | c.3060G>A p.R1020= (on ENST00000283426; = p.R1376= on NM_052909.5) | Silent (SNP) | VAF 31/244 reads (13%) | called by muse, mutect2, varscan2
- PNKP | c.192G>A p.V64= | Silent (SNP) | VAF 10/270 reads (4%) | catalogued as COSV100464871, COSV59275557; called by muse, mutect2
- PRB3 | c.87C>T p.P29= | Silent (SNP) | VAF 59/326 reads (18%) | called by muse, mutect2, varscan2
- PRPF6 | c.1179T>C p.L393= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs144549836; called by muse, mutect2, varscan2
- PSMD9 | c.495G>A p.V165= | Silent (SNP) | VAF 34/241 reads (14%) | called by muse, mutect2, varscan2
- R3HDM2 | c.960C>G p.L320= | Silent (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2, varscan2
- RB1CC1 | c.2928G>A p.L976= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as rs748204427; called by muse, mutect2, varscan2
- RELN | c.816A>T p.S272= | Silent (SNP) | VAF 82/317 reads (26%) | called by muse, mutect2, varscan2
- RHD | c.132C>G p.L44= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs769626782; called by muse, mutect2, varscan2
- ROR2 | c.66C>T p.A22= | Silent (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- RP1 | c.588C>T p.V196= | Silent (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.1899C>T p.F633= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- RYR1 | c.486C>A p.V162= | Silent (SNP) | VAF 308/452 reads (68%) | called by muse, mutect2, varscan2
- SAMD15 | c.1959A>G p.L653= | Silent (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- SCGN | c.186G>A p.V62= | Silent (SNP) | VAF 22/265 reads (8%) | catalogued as COSV58545969; called by muse, mutect2
- SCN4A | c.1194T>C p.A398= | Silent (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- SDS | c.69C>A p.A23= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV57452915; called by muse, mutect2, varscan2
- SENP6 | c.1368C>T p.F456= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs1339838983; called by muse, mutect2, varscan2
- SLC26A4 | c.480C>T p.H160= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- SLC4A9 | c.168C>G p.L56= | Silent (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- SMG1 | c.4263C>A p.L1421= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV101246102; called by muse, mutect2
- SOX17 | c.54C>T p.S18= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs1349507782; called by muse, mutect2
- SP5 | c.291G>A p.Q97= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as rs1187111198; called by muse, mutect2, varscan2
- STEAP4 | c.378A>G p.P126= | Silent (SNP) | VAF 28/160 reads (18%) | called by muse, varscan2
- SUPT6H | c.2646A>C p.V882= | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- TANC1 | c.990G>T p.G330= | Silent (SNP) | VAF 55/195 reads (28%) | called by muse, mutect2, varscan2
- TBL2 | c.516G>T p.G172= | Silent (SNP) | VAF 36/164 reads (22%) | called by muse, mutect2, varscan2
- TLR4 | c.1908G>A p.V636= (on ENST00000355622 / NM_138554.5; = p.V596= on NM_003266.4) | Silent (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- TMEM132A | c.1974C>A p.P658= (on ENST00000453848 / NM_178031.3; = p.P659= on NM_017870.4) | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV50002464, COSV50013176; called by muse, mutect2, varscan2
- TMPRSS11A | c.69C>A p.L23= | Silent (SNP) | VAF 36/226 reads (16%) | called by muse, mutect2, varscan2
- TMPRSS11E | c.939G>A p.V313= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs1208767776, COSV59520232; called by muse, mutect2
- TMTC4 | c.696G>T p.A232= (on ENST00000376234 / NM_001350577.2; = p.A251= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100168442; called by muse, mutect2, varscan2
- TRMT13 | c.228G>A p.L76= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV54928386; called by muse, mutect2, varscan2
- TRPM3 | c.4521C>T p.R1507= (on ENST00000357533 / NM_001366142.2; = p.R1362= on NM_020952.6) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV62585351; called by muse, mutect2, varscan2
- TTC23L | c.375G>A p.L125= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV72205902; called by muse, mutect2
- UNC79 | c.7332C>G p.G2444= (on ENST00000393151 / NM_001346218.2; = p.G2267= on NM_020818.5) | Silent (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- VSX2 | c.921G>T p.A307= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs768286032, COSV56218174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WBP1 | c.456C>A p.S152= | Silent (SNP) | VAF 34/162 reads (21%) | called by muse, varscan2
- YTHDF1 | c.1521C>T p.D507= | Silent (SNP) | VAF 50/312 reads (16%) | called by muse, varscan2
- ZFP36L1 | c.828C>A p.T276= | Silent (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- ZKSCAN8 | c.1251G>A p.Q417= | Silent (SNP) | VAF 9/192 reads (5%) | catalogued as COSV57640468; called by muse, mutect2
- ZNF445 | c.2784G>C p.P928= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV101253700; called by muse, mutect2, varscan2
- ZNF695 | c.633G>T p.P211= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- AC008758.3 | n.389G>C | RNA (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- AC092471.1 | n.939G>T | RNA (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2, varscan2
- AC124067.4 | n.2104C>A | RNA (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- AC245033.1 | c.1174+760G>A | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as rs921026792; called by muse, mutect2, varscan2
- ADAMTS13 | c.*73C>T | 3'UTR (SNP) | VAF 73/413 reads (18%) | catalogued as COSV52469446; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852023 C>T | 3'Flank (SNP) | VAF 99/244 reads (41%) | called by muse, mutect2, varscan2
- AURKC | c.-11C>A | 5'UTR (SNP) | VAF 38/336 reads (11%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.1112G>A | RNA (SNP) | VAF 18/81 reads (22%) | catalogued as rs574317893; called by muse, mutect2, varscan2
- BEND6 | chr6:56954597 G>C | 5'Flank (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- CA13 | c.37+559T>A | Intron (SNP) | VAF 24/378 reads (6%) | called by muse, mutect2
- CACNA1A | c.6322-31C>G | Intron (SNP) | VAF 12/190 reads (6%) | catalogued as rs201171243; called by muse, mutect2
- CCDC162P | n.3276+67C>G | Intron (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- CCDC91 | c.*59C>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs889839091; called by muse, mutect2
- CCL4L2 | c.191+145C>T | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- CDH23 | c.3369+398G>A | Intron (SNP) | VAF 30/170 reads (18%) | catalogued as rs753237116, COSV56455391; called by muse, mutect2, varscan2
- CDK16 | c.-174C>A | 5'UTR (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- CEP41 | c.*1475C>T | 3'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- CKAP2 | c.-56G>T | 5'UTR (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- CLK2P1 | n.645A>G | RNA (SNP) | VAF 76/340 reads (22%) | catalogued as rs997388423; called by muse, mutect2, varscan2
- CLRN1 | c.254-868C>G | Intron (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- CNGB3 | chr8:86569329 C>T | 3'Flank (SNP) | VAF 54/204 reads (26%) | called by muse, varscan2
- CNTN2 | c.392-18C>T | Intron (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12411C>G | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- DEFB119 | c.61+1211G>T | Intron (SNP) | VAF 82/234 reads (35%) | catalogued as COSV59268576; called by muse, mutect2, varscan2
- DPP10 | c.61-146986G>A | Intron (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- EFHC1 | c.*1922C>G | 3'UTR (SNP) | VAF 38/357 reads (11%) | called by muse, mutect2, varscan2
- FOXN3 | c.746-40375C>T | Intron (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- FYB1 | c.1359+36T>G | Intron (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- GABRB3 | c.241-20985G>A | Intron (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- GGNBP1 | n.846+1056C>A | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- GYS2 | c.-20C>T | 5'UTR (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.133G>A | RNA (SNP) | VAF 28/190 reads (15%) | called by muse, mutect2, varscan2
- KANSL1 | c.-89-24108G>T | Intron (SNP) | VAF 46/184 reads (25%) | called by muse, mutect2, varscan2
- LDB2 | c.891+2658G>A | Intron (SNP) | VAF 6/57 reads (11%) | catalogued as rs1487705036; called by muse, mutect2, varscan2
- LIFR | c.257+23C>G | Intron (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- LINC01579 | n.545C>A | RNA (SNP) | VAF 4/39 reads (10%) | called by mutect2, varscan2
- MAX | c.37-61G>A | Intron (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2
- MIA2 | c.249+131T>A | Intron (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- MMP14 | c.108+393G>C | Intron (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- MOGS | c.777-35G>A | Intron (SNP) | VAF 28/125 reads (22%) | catalogued as COSV99281143; called by muse, mutect2, varscan2
- MORF4L1 | c.40+58C>G | Intron (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-4579_2164-4575del | Intron (DEL) | VAF 14/114 reads (12%) | called by mutect2, pindel
- MT1E | c.94+109C>A | Intron (SNP) | VAF 24/108 reads (22%) | called by muse, varscan2
- NBPF22P | n.394G>C | RNA (SNP) | VAF 61/405 reads (15%) | called by muse, mutect2, varscan2
- NTPCR | c.505-1717G>A | Intron (SNP) | VAF 16/166 reads (10%) | catalogued as rs1167483107; called by muse, mutect2, varscan2
- NUP58 | c.1436-733A>T | Intron (SNP) | VAF 12/404 reads (3%) | called by muse, mutect2
- OFCC1 | n.319C>A | RNA (SNP) | VAF 24/331 reads (7%) | called by muse, mutect2
- OR2W5 | n.432C>A | RNA (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- OR3A4P | n.1198C>T | RNA (SNP) | VAF 14/64 reads (22%) | catalogued as rs747882648; called by muse, mutect2, varscan2
- PAX3 | chr2:222201165 A>G | 3'Flank (SNP) | VAF 11/177 reads (6%) | called by muse, mutect2
- PAX3 | chr2:222201362 G>C | 3'Flank (SNP) | VAF 38/242 reads (16%) | catalogued as COSV100400015; called by muse, mutect2, varscan2
- PBX3 | c.275-71920G>C | Intron (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- PDE7B | c.83-70361C>T | Intron (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- PITPNB | c.*15G>C | 3'UTR (SNP) | VAF 26/167 reads (16%) | called by muse, mutect2, varscan2
- PLOD2 | chr3:146163639 C>G | 5'Flank (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- PRPF19 | c.*378G>T | 3'UTR (SNP) | VAF 72/198 reads (36%) | called by muse, varscan2
- PSMD5 | chr9:120815767 C>G | 3'Flank (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.3746-2713C>T | Intron (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- RNU6-955P | chr17:4616820 A>T | 3'Flank (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- RPGR | c.2520+172G>A | Intron (SNP) | VAF 24/51 reads (47%) | catalogued as COSV58837503; called by muse, mutect2, varscan2
- RPS26 | c.-46G>T | 5'UTR (SNP) | VAF 40/155 reads (26%) | called by muse, mutect2, varscan2
- SEC14L2 | c.424-92C>G | Intron (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- SIX6 | c.-25C>G | 5'UTR (SNP) | VAF 42/94 reads (45%) | catalogued as rs762783680; called by muse, mutect2, varscan2
- SP4 | c.1679-5956G>C | Intron (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- SPATA13 | c.290-5383G>A | Intron (SNP) | VAF 34/175 reads (19%) | called by muse, varscan2
- SSC5D | c.2785+2925G>A | Intron (SNP) | VAF 21/156 reads (13%) | catalogued as rs939782151; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.-33G>T | 5'UTR (SNP) | VAF 66/197 reads (34%) | called by muse, mutect2, varscan2
- STEAP1B | c.706-18774T>C | Intron (SNP) | VAF 56/275 reads (20%) | catalogued as rs1033129808; called by muse, mutect2, varscan2
- TAAR3P | n.917G>T | RNA (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- TALDO1 | c.-10C>G | 5'UTR (SNP) | VAF 26/132 reads (20%) | catalogued as rs769450671; called by muse, mutect2, varscan2
- TBX15 | c.1025-5371G>C | Intron (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- TMEM135 | c.*1493T>C | 3'UTR (SNP) | VAF 22/490 reads (4%) | called by muse, mutect2
- TMEM184A | c.645-483A>C | Intron (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- TOM1 | c.138-152G>A | Intron (SNP) | VAF 28/158 reads (18%) | called by muse, mutect2, varscan2
- TRMT5 | c.11+67C>G | Intron (SNP) | VAF 9/41 reads (22%) | catalogued as rs1004945665; called by muse, mutect2, varscan2
- TTC19 | c.*722T>G | 3'UTR (SNP) | VAF 46/399 reads (12%) | called by muse, mutect2, varscan2
- UTP18 | c.*44T>C | 3'UTR (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.-14T>A | 5'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- ZNF655 | c.136+1207C>G | Intron (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99402178; called by muse, mutect2, varscan2
